CCDI case PBCCYI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b5be233d-8410-468b-8dba-798a0216ece6

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Tumor cells, uncertain whether benign or malignant: ICD-O-3 morphology code: 8001/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.6 years (2,409 days).

Biospecimens (3 samples)
- Sample 0DOV8N: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DOV93: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DOV98: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
